CPTAC case 01BR044 — Breast — Squamous Cell Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/f2752dae-cad9-486d-95cf-dcbde49936ea

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/33; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 84.9 years (30,994 days); AJCC pathologic stage: Stage III; Prior malignancy: no.

Biospecimens (2 samples)
- Sample CPT001846: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample CPT001849: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
